TCGA case TCGA-14-1456 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Emory University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0fe6684a-5ab2-4999-b69d-d99aa5679c97

Demographics
Sex at birth: male; Race: white; Age at index: 23 years; Vital status: Alive.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 23.8 years (8,710 days); Year of diagnosis: 2006; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Dexamethasone; Treatment intent type: Adjuvant; Days to treatment start: 0 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Arsenic Trioxide; Treatment intent type: Adjuvant; Days to treatment start: 25 days; Days to treatment end: 70 days; Number of cycles: 13; Treatment dose: 291 mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 28 days; Days to treatment end: 70 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Dexamethasone; Initial disease status: Progressive Disease; Days to treatment start: 98 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 102 days; Days to treatment end: 1,128 days (3.1 years); Treatment dose: 11,704 mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Erlotinib Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 102 days; Days to treatment end: 549 days (1.5 years); Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 1,129 days (3.1 years); Days to treatment end: 1,246 days (3.4 years); Treatment dose: 3,344 mg; Treatment outcome: Treatment Ongoing.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 24.1 years (8,808 days); Days to diagnosis: 98 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 98 (post initial treatment): Progression or recurrence: Yes; Days to progression: 98 days.
- Days to follow up: 1,246 days (3.4 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Post Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-14-1456-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 0.5; Shortest dimension: 0.2.
  Slide TCGA-14-1456-01B-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 5.
  Slide TCGA-14-1456-01B-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-14-1456-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample TCGA-14-1456-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Dexamthasone.
- Drug treatment 2: Pharmaceutical therapy drug name: Tarceva.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 3: Pharmaceutical therapy drug name: Arsenic Tnoxide.
- Drug treatment 5: Pharmaceutical therapy drug name: Avastin.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,246 days; disease-specific survival: no event (censored), 1,246 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 98 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-14-1456-01B-01D-0784-01): tumor purity 0.8, ploidy 2.04, whole-genome doublings 0.
